Somatic mutation profile of tumor specimen TCGA-2Y-A9GZ-01A (aliquot TCGA-2Y-A9GZ-01A-11D-A38X-10) from TCGA case TCGA-2Y-A9GZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 82.4 years (30,082 days).
Specimen TCGA-2Y-A9GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4980786-b80d-41c5-af1d-a32c562843f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GZ-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GZ-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd9c588d-831e-422f-ae0d-e5d79f11aa3f

The open-access MAF lists 112 somatic variants for this specimen: 80 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 29, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 4, Frame Shift Ins 3, 5'UTR 2, Splice Region 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM20 | c.605G>C p.W202S | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV99833426; called by muse, mutect2, varscan2
- AGO1 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100940830; called by muse, mutect2, varscan2
- AKAP6 | c.6329A>T p.Y2110F | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99800624; called by muse, mutect2, varscan2
- AL121899.2 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101198447; called by muse, varscan2
- APBA2 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs746831479, COSV101382197, COSV101382357; called by muse, mutect2, varscan2
- APC | c.8194G>C p.D2732H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99967717; called by muse, mutect2, varscan2
- ARSH | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101139847; called by muse, mutect2, varscan2
- ATAD3B | c.*296G>T | Splice Region (SNP) | VAF 104/246 reads (42%) | catalogued as rs1281098355, COSV100426434, COSV58023194; called by muse, mutect2, varscan2
- ATF7IP | c.2410A>T p.T804S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99661621; called by muse, mutect2, varscan2
- BCL9 | c.4076C>A p.P1359H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99325098; called by muse, mutect2, varscan2
- BTLA | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569707; called by muse, mutect2
- CACNA1E | c.4226T>C p.V1409A | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100702474; called by muse, mutect2, varscan2
- CDH15 | c.1537del p.H513Tfs*9 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs763850576, COSV57025343; called by mutect2, varscan2
- CEP128 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99824602; called by muse, mutect2, varscan2
- CHSY3 | c.1456A>T p.S486C | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100519054; called by muse, mutect2, varscan2
- CIC | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV99359525; called by muse, mutect2, varscan2
- CYBB | c.1583C>G p.P528R | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV101059750; called by muse, mutect2, varscan2
- DDX49 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV53229382, COSV99447434; called by muse, mutect2, varscan2
- DGKQ | c.2316-1G>A p.X772_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as rs1200427668, COSV99297791; called by muse, mutect2, varscan2
- DNAAF3 | c.1557G>T p.E519D (on ENST00000524407 / NM_001256715.2; = p.E566D on NM_178837.4) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV100787934; called by muse, mutect2, varscan2
- DNAI3 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 110/521 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs149091067; called by muse, mutect2, varscan2
- ELF3 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100668761; called by muse, mutect2, varscan2
- FAM131B | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100578023; called by muse, mutect2, varscan2
- FAM184A | c.2731A>G p.I911V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100137757; called by muse, mutect2, varscan2
- FERMT2 | c.872T>G p.I291S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100448886; called by muse, mutect2
- FMN1 | c.2988C>A p.S996R (on ENST00000616417 / NM_001277313.2; = p.S773R on NM_001103184.4) | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.162); catalogued as COSV100568615; called by muse, mutect2, varscan2
- GPR19 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100196869; called by muse, mutect2, varscan2
- GRB10 | c.1133T>A p.L378* (on ENST00000398812; = p.L332* on NM_001001549.3) | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | catalogued as COSV100240403; called by muse, mutect2, varscan2
- GTF3C1 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV100649380; called by muse, mutect2, varscan2
- HTT | c.9255G>C p.Q3085H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100750725; called by muse, mutect2, varscan2
- ICE1 | c.4063C>G p.Q1355E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99664649; called by muse, mutect2, varscan2
- IRAK1 | c.1119C>A p.S373R | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100888988; called by muse, mutect2, varscan2
- IWS1 | c.2240G>T p.G747V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99767204; called by muse, mutect2, varscan2
- LAD1 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1279795745, COSV100943849; called by muse, mutect2, varscan2
- LHX9 | c.1024C>A p.L342I | Missense Mutation (SNP) | VAF 113/186 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.294); catalogued as COSV100435863; called by muse, mutect2, varscan2
- MARVELD2 | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766199160, COSV100347570; called by muse, mutect2, varscan2
- MCMBP | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 57/101 reads (56%) | catalogued as COSV100750081, COSV63508594; called by muse, mutect2, varscan2
- MED13 | c.4091G>T p.G1364V | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67267659; called by muse, varscan2
- MGAT3 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201303175, COSV100361867; called by muse, mutect2, varscan2
- MKNK2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1339923062, COSV99170257; called by muse, mutect2, varscan2
- MYO5B | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs765665080, COSV53217846; called by muse, mutect2, varscan2
- NPY1R | c.700-1G>C p.X234_splice | Splice Site (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99648729; called by muse, mutect2, varscan2
- OR2J3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101013624, COSV101013677; called by muse, mutect2, varscan2
- OR4X2 | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100183231; called by muse, mutect2, varscan2
- OR9Q2 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285428; called by muse, mutect2, varscan2
- PABPC1L | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99407790, COSV99408213; called by muse, mutect2, varscan2
- PAK5 | c.977T>C p.M326T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100781314, COSV62036254; called by muse, mutect2, varscan2
- PCLO | c.6169A>T p.K2057* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100432179; called by muse, mutect2, varscan2
- PEG3 | c.1420C>A p.H474N | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99688838; called by muse, mutect2
- PSMF1 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs777003948, COSV99850484; called by muse, mutect2, varscan2
- PTPRO | c.3613A>T p.I1205F (on ENST00000281171 / NM_030667.3; = p.I1177F on NM_002848.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV99840471; called by muse, mutect2, varscan2
- RFX5 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs764649554, COSV100923874; called by muse, mutect2, varscan2
- RHCE | c.448T>A p.L150I | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99604005; called by muse, mutect2
- RXRB | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100553958; called by muse, varscan2
- SIGLEC8 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as COSV58473007; called by muse, mutect2, varscan2
- SLC16A10 | c.1333C>A p.L445M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV100920873; called by muse, mutect2
- SRSF8 | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.444); catalogued as COSV101475799; called by muse, mutect2, varscan2
- SULT1C4 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 47/165 reads (28%) | catalogued as COSV55597294; called by muse, mutect2, varscan2
- SYTL2 | c.2278G>T p.A760S (on ENST00000528231 / NM_001162951.2; = p.A736S on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV100314201; called by muse, mutect2, varscan2
- TRIP12 | c.2314T>A p.W772R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99390177; called by muse, mutect2, varscan2
- TRO | c.2399G>T p.S800I | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); catalogued as COSV99436390; called by muse, mutect2, varscan2
- UBE2Q2 | c.1097-1G>A p.X366_splice | Splice Site (SNP) | VAF 11/16 reads (69%) | catalogued as COSV51196894, COSV99143265; called by muse, mutect2, varscan2
- UGGT2 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100948669; called by muse, mutect2, varscan2
- VPS16 | c.1095G>C p.E365D | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV100988475; called by muse, mutect2, varscan2
- WDR91 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.833); catalogued as COSV100615689; called by muse, mutect2, varscan2
- XIRP2 | c.7850A>G p.N2617S (on ENST00000628543; = p.N2792S on NM_152381.6) | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99742610; called by muse, mutect2, varscan2
- ZBBX | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs572404264, COSV100283929; called by muse, mutect2, varscan2
- ZNF185 | c.1391A>G p.E464G | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV100248373; called by muse, mutect2, varscan2
- ZNF365 | c.1122C>A p.C374* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV101237959, COSV101237992, COSV67925145; called by muse, mutect2, varscan2
- ZNF391 | c.781A>T p.I261F | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.337); catalogued as COSV99772606; called by muse, mutect2, varscan2
- ZNF521 | c.3658+1G>T p.X1220_splice | Splice Site (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100832100; called by muse, mutect2, varscan2
- AADAT | c.1139_1147del p.L380_P383delinsS | In Frame Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, varscan2
- ACACA | c.6645_6651del p.Y2216Rfs*2 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | called by mutect2, pindel, varscan2
- ALB | c.1344_1348del p.E449Lfs*13 | Frame Shift Del (DEL) | VAF 48/195 reads (25%) | called by mutect2, pindel, varscan2
- CPA1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- HERC1 | c.12654dup p.L4219Tfs*16 | Frame Shift Ins (INS) | VAF 40/158 reads (25%) | called by mutect2, varscan2
- MDGA1 | c.2078dup p.V695Gfs*24 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- NCOA3 | c.915dup p.S306* | Frame Shift Ins (INS) | VAF 54/290 reads (19%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.9132del p.P3045Qfs*11 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, pindel, varscan2
- TEP1 | c.6895_6901del p.N2299Lfs*4 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- ALDOC | c.828C>T p.S276= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs369962449; called by muse, mutect2, varscan2
- ANXA5 | c.339T>C p.I113= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99634357; called by muse, mutect2, varscan2
- APH1B | c.141G>A p.L47= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV99971526; called by muse, mutect2, varscan2
- ARMC8 | c.1935C>A p.I645= (on ENST00000469044 / NM_001363941.2; = p.I631= on NM_015396.6) | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV100509603; called by muse, mutect2, varscan2
- ATP10B | c.1419T>C p.D473= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100469385, COSV58777956; called by muse, mutect2, varscan2
- B3GNT4 | c.756C>T p.P252= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99928206; called by muse, mutect2, varscan2
- CCNG1 | c.111T>C p.I37= | Silent (SNP) | VAF 70/152 reads (46%) | catalogued as COSV100546730; called by muse, mutect2, varscan2
- CD99L2 | c.54C>A p.T18= | Silent (SNP) | VAF 53/106 reads (50%) | catalogued as COSV100306459; called by muse, mutect2, varscan2
- DPP6 | c.966T>C p.R322= (on ENST00000377770 / NM_001364500.2; = p.R260= on NM_001936.5) | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs762389893, COSV100125387; called by muse, mutect2, varscan2
- FANCD2 | c.778T>C p.L260= | Silent (SNP) | VAF 60/192 reads (31%) | catalogued as rs756621826, COSV99811222; called by muse, mutect2, varscan2
- FBN2 | c.5178C>T p.V1726= | Silent (SNP) | VAF 103/234 reads (44%) | catalogued as COSV99327264; called by muse, mutect2, varscan2
- HENMT1 | c.1027C>T p.L343= | Silent (SNP) | VAF 80/168 reads (48%) | catalogued as COSV100898658; called by muse, mutect2, varscan2
- HRH3 | c.960C>T p.L320= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV100420581; called by muse, mutect2, varscan2
- MED30 | c.42G>T p.G14= | Silent (SNP) | VAF 61/119 reads (51%) | catalogued as COSV52066587, COSV99816024; called by muse, mutect2, varscan2
- NAA80 | c.9G>A p.L3= (on ENST00000417393 / NM_001200018.2; = p.L25= on NM_012191.4) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs781901007, COSV99807648; called by mutect2, varscan2
- PCDHA13 | c.2190C>A p.G730= | Silent (SNP) | VAF 38/186 reads (20%) | catalogued as COSV56504226, COSV99166229; called by muse, mutect2, varscan2
- PPFIA2 | c.2592G>T p.G864= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV100333277; called by muse, mutect2, varscan2
- PPP1CB | c.18G>T p.L6= | Silent (SNP) | VAF 165/251 reads (66%) | catalogued as COSV99941834; called by muse, mutect2, varscan2
- PRAMEF2 | c.645G>T p.T215= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs376186859; called by muse, mutect2, varscan2
- QKI | c.786C>T p.V262= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as COSV99274899, COSV99275176; called by muse, mutect2, varscan2
- RFX7 | c.4008C>T p.C1336= (on ENST00000559447 / NM_001368074.1; = p.C1433= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs768475607, COSV57962808, COSV57965657; called by muse, mutect2, varscan2
- RNF157 | c.1590C>T p.D530= | Silent (SNP) | VAF 61/202 reads (30%) | catalogued as COSV99486942; called by muse, mutect2, varscan2
- SNAP91 | c.1005T>A p.S335= | Silent (SNP) | VAF 61/81 reads (75%) | catalogued as rs766101597, COSV99535163; called by muse, mutect2, varscan2
- SOX11 | c.621C>T p.G207= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs745910593, COSV100431069; called by muse, varscan2
- TBX22 | c.750C>T p.S250= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as COSV100960607, COSV100960769; called by muse, mutect2, varscan2
- TMPRSS4 | c.207C>T p.H69= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV101449382; called by muse, mutect2, varscan2
- TRIM37 | c.87T>A p.P29= | Silent (SNP) | VAF 258/513 reads (50%) | catalogued as COSV99232873; called by muse, mutect2, varscan2
- TTN | c.9396A>G p.G3132= (on ENST00000591111; = p.G3086= on NM_003319.4) | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs1358537431; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP16 | c.504T>C p.S168= | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as COSV100537931; called by muse, mutect2, varscan2
- ELAVL4 | chr1:50106353 G>A | 5'Flank (SNP) | VAF 30/59 reads (51%) | catalogued as COSV100836734, COSV100836921; called by muse, mutect2, varscan2
- HOPX | c.-2C>T | 5'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100497033; called by muse, mutect2, varscan2
- MDFIC | c.-76C>G | 5'UTR (SNP) | VAF 29/79 reads (37%) | catalogued as COSV99995110; called by muse, mutect2, varscan2
